Somatic mutation profile of tumor specimen TCGA-R6-A6XQ-01B (aliquot TCGA-R6-A6XQ-01B-11D-A33E-09) from TCGA case TCGA-R6-A6XQ, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: G3; Age at diagnosis: 58.6 years (21,410 days).
Specimen TCGA-R6-A6XQ-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4c75e71-5d2d-44a7-be12-e6fb16aec956.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-R6-A6XQ-10A (Blood Derived Normal), aliquot TCGA-R6-A6XQ-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/759ab7d8-c3a4-4c7b-b5a9-8009f4e274b6

The open-access MAF lists 82 somatic variants for this specimen: 61 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 20, Nonsense Mutation 4, Frame Shift Del 3, Splice Site 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.97T>G p.S33A | Missense Mutation (SNP) | VAF 8/16 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519886, COSV62688086, COSV62689225, COSV62704131; ClinVar: likely pathogenic; called by muse, mutect2
- POMGNT1 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 16/93 reads (17%) | catalogued as rs193919337, CM030725, COSV64339395; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 29/31 reads (94%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS8 | c.2339G>A p.R780Q | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs771285887; called by muse, mutect2, varscan2
- ADCY8 | c.2359G>A p.V787I | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.029); catalogued as rs747001489, COSV53917026; called by muse, mutect2, varscan2
- BRINP1 | c.1589G>A p.S530N | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV56306520; called by muse, mutect2, varscan2
- CACNA1H | c.2243C>T p.A748V | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs770371468, CM032208, COSV61987315; called by muse, mutect2, varscan2
- CACNA1I | c.4970G>A p.R1657Q | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1016081416; called by muse, mutect2, varscan2
- CCDC130 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 31/36 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1222629626; called by muse, mutect2, varscan2
- CHRNB4 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs753819024, COSV55715360; called by muse, mutect2, varscan2
- COL22A1 | c.2539C>T p.P847S | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.968); catalogued as COSV100277190; called by muse, mutect2, varscan2
- CRYGD | c.349C>G p.R117G | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as rs762126299; called by muse, mutect2, varscan2
- GFRA1 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1005537154, COSV100815894, COSV62602441; called by muse, mutect2, varscan2
- HCN4 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759685985, COSV56086261; called by muse, mutect2, varscan2
- HSPB8 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99931147; called by muse, mutect2, varscan2
- INHBA | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54220107; called by muse, mutect2, varscan2
- IRX1 | c.1180G>A p.V394I | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV57359216; called by muse, mutect2, varscan2
- JPH2 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65903890; called by muse, mutect2, varscan2
- JPH3 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs769968009; called by muse, mutect2, varscan2
- LMBR1L | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as rs370079049; called by muse, mutect2, varscan2
- LRRTM1 | c.1258G>C p.E420Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.702); catalogued as COSV54441121; called by muse, mutect2, varscan2
- MELTF | c.362T>C p.I121T | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs143266319; called by muse, mutect2, varscan2
- MMP17 | c.589G>A p.G197S | Missense Mutation (SNP) | VAF 103/158 reads (65%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.635); catalogued as rs370404573; called by muse, mutect2, varscan2
- MTNR1A | c.736C>G p.L246V | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.129); catalogued as COSV56158315; called by muse, mutect2, varscan2
- NDUFS3 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV55454204; called by muse, mutect2
- OSBPL5 | c.2191C>T p.R731W | Missense Mutation (SNP) | VAF 71/139 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as rs778874744; called by muse, mutect2, varscan2
- PKHD1L1 | c.6567del p.K2189Nfs*27 | Frame Shift Del (DEL) | VAF 7/35 reads (20%) | catalogued as rs769716668, COSV65737892; called by mutect2, pindel, varscan2
- PLA2G2F | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as rs768543972, COSV64280054; called by muse, mutect2, varscan2
- PRDM7 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs781531795; called by muse, mutect2, varscan2
- SCN3A | c.2812C>T p.R938C | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1485299077, COSV51806715, COSV99327262; called by muse, mutect2, varscan2
- SCTR | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs146299407; called by muse, mutect2, varscan2
- SF3A1 | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); catalogued as rs1208126048; called by muse, mutect2, varscan2
- SPON1 | c.2212C>T p.R738W | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs782356380, COSV59958839; called by muse, mutect2, varscan2
- WDR59 | c.1579G>A p.G527R | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1408871114; called by muse, mutect2, varscan2
- XKR7 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs1444236059, COSV73813499; called by muse, mutect2, varscan2
- ZFHX4 | c.6553C>T p.R2185* | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as COSV51441550, COSV51500998; called by muse, mutect2, varscan2
- ZSCAN1 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs200190736, COSV56607542; called by muse, mutect2, varscan2
- ACTR8 | c.1088A>G p.H363R | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.72); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- C8A | c.1603+1G>T p.X535_splice | Splice Site (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
- CALHM6 | c.619C>A p.L207M | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CCNE1 | c.632A>G p.H211R | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CNRIP1 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 45/69 reads (65%) | SIFT deleterious (0.05); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- CYP24A1 | c.903C>A p.F301L | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- DCC | c.2235G>A p.W745* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | called by muse, varscan2
- ENPP5 | c.881C>G p.T294S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- GZF1 | c.559_562del p.R187Pfs*18 | Frame Shift Del (DEL) | VAF 20/100 reads (20%) | called by mutect2, pindel, varscan2
- KCNJ8 | c.82C>T p.R28* | Nonsense Mutation (SNP) | VAF 34/54 reads (63%) | called by muse, mutect2, varscan2
- KNTC1 | c.5973+6_5973+9del p.X1991_splice | Splice Site (DEL) | VAF 9/37 reads (24%) | called by pindel, varscan2
- LBR | c.155A>G p.N52S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- LTBP3 | c.3467C>T p.A1156V (on ENST00000301873 / NM_001130144.3; = p.A1109V on NM_021070.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.59); PolyPhen benign (0.183); called by muse, mutect2
- NCKAP5 | c.760A>T p.I254F | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- NCOR2 | c.6179G>T p.S2060I | Missense Mutation (SNP) | VAF 82/138 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- NIFK | c.242G>A p.R81K | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- PCDHB14 | c.2125G>A p.V709M | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- PLEK2 | c.962T>A p.L321H | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAPGEF4 | c.396C>A p.S132R | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCN3A | c.984G>C p.L328F | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- TENM4 | c.7822C>A p.H2608N | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TRERF1 | c.2129C>T p.P710L | Missense Mutation (SNP) | VAF 29/34 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TSHZ2 | c.1742A>T p.K581M | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- WDR33 | c.2374del p.E792Rfs*10 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | called by mutect2, pindel, varscan2
- ABCB5 | c.933C>A p.S311= | Silent (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- CASZ1 | c.3138C>T p.D1046= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV59734376; called by muse, mutect2, varscan2
- CCR2 | c.1035G>T p.V345= | Silent (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- COL17A1 | c.2577A>T p.P859= | Silent (SNP) | VAF 33/66 reads (50%) | called by muse, mutect2, varscan2
- EVPL | c.5253C>T p.A1751= | Silent (SNP) | VAF 13/20 reads (65%) | catalogued as rs199559105, COSV56908960; called by muse, mutect2, varscan2
- GREB1 | c.4356G>A p.T1452= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs543467857; called by muse, mutect2, varscan2
- GRIN2B | c.1608C>A p.V536= | Silent (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2
- KRT72 | c.321G>A p.L107= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs538625481; called by muse, mutect2, varscan2
- LRP1B | c.4980A>G p.S1660= | Silent (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- MMP25 | c.207G>A p.A69= | Silent (SNP) | VAF 47/73 reads (64%) | called by muse, mutect2, varscan2
- PITPNM3 | c.492C>T p.V164= | Silent (SNP) | VAF 14/59 reads (24%) | called by muse, mutect2, varscan2
- RMND5A | c.498C>T p.V166= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV52154282; called by muse, mutect2, varscan2
- SARDH | c.1902G>T p.P634= | Silent (SNP) | VAF 44/88 reads (50%) | catalogued as rs377363025; called by muse, varscan2
- SLC8A2 | c.831G>A p.P277= | Silent (SNP) | VAF 17/22 reads (77%) | catalogued as rs779415776; called by muse, mutect2, varscan2
- SPAG9 | c.3180C>T p.V1060= (on ENST00000262013 / NM_001130528.3; = p.V1046= on NM_003971.6) | Silent (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- SPECC1L | c.1305C>T p.N435= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs200078151; called by muse, mutect2, varscan2
- ST7 | c.318A>T p.G106= | Silent (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- STX17 | c.882C>G p.P294= | Silent (SNP) | VAF 8/11 reads (73%) | called by muse, mutect2, varscan2
- ZFHX3 | c.2757C>T p.G919= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs141768802; called by muse, mutect2, varscan2
- ZNF813 | c.1218C>T p.T406= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs372871030; called by muse, mutect2, varscan2
- NBPF11 | c.-548-3153C>T | Intron (SNP) | VAF 106/163 reads (65%) | catalogued as rs1174618270; called by muse, mutect2, varscan2
